Surgical pathology report (de-identified scan), TCGA case TCGA-98-A53D, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Washington University - Alabama, specimen TCGA-98-A53D-01A (Primary Tumor).

[page 1 of 3]
Patient Name	MR#	Observation Date	Last Edited Date
--------------	-----	------------------	------------------

SURGICAL PATHOLOGY CASE:

Diagnosis

- A. Lymph node, level IV-R, excision: - One lymph node negative for malignancy (0/1).
- B. Lymph node, level II-R, excision: - One lymph node negative for malignancy (0/1).
- C. Lymph node, second level IV-R, excision: - One lymph node negative for malignancy (0/1).
- D. Lymph node, second level II-R, excision: - One lymph node negative for malignancy (0/1).
- E. Lymph node, third level IV-R, excision: - One lymph node negative for malignancy (0/1).
- F. Lymph node, level X, excision: - One lymph node negative for malignancy (0/1).
- G. Lymph node, level VII, excision: - One lymph node negative for malignancy (0/1).
- H. Lymph node, level VIII, excision: - Negative for malignancy. - No lymph node present.
- I. Lymph node, level IX, excision: - One lymph node negative for malignancy (0/1).
- J. Lymph node, level X-R, excision: - Five lymph nodes negative for malignancy (0/5).
- K. Lymph node, level XI, excision: - One lymph node negative for malignancy (0/1).
- L. Lung, right upper lobe, excision: - Squamous cell carcinoma, moderately differentiated, keratinizing, measuring 5.2 cm in maximum dimension. - Carcinoma invades into the visceral pleura. - One peribronchial lymph node negative for malignancy (0/1). - Surgical margins are negative for malignancy.
- M. Bronchial margin, excision: - Negative for malignancy.

Clinical Information: The patient is a year old male with right lung mass.

Frozen Section Diagnosis

- AFS1: Lymph node, IV-R, excision: - Negative for malignancy.
- BFS1: Lymph node, II-R, excision: - Negative for malignancy.
- CFS1: Lymph node, second IV-R, excision: - Negative for malignancy.
- DFS1: Lymph node, second II-R, excision: - Negative for malignancy.
- EFS1: Lymph node, third IV-R, excision: - Negative for malignancy.
- GFS1: Lymph node, level VII, excision: - Negative for malignancy.
- HFS1: Lymph node, level VIII, excision: - Negative for malignancy. - No lymph node present.
- IFS1: Lymph node, level IX, excision: - Negative for malignancy.
- LFS1: Lung, right upper lobe, resection: - Squamous cell carcinoma.
- MFS1: Bronchial margin, excision: - Negative for malignancy. 1 per

ICD - 10 - 3
Carcinoma, Squamous cell, Keratinizing,
NOS 8071/3
Site: Lung, @ upper lobe C34.1
11/25/12

Gross Description

The specimen is received in thirteen containers each labeled with the patient's name and medical record number. The first container is additionally labeled "IV-R lymph node". The specimen consists of an orange frozen section cassette labeled "A1" containing tan-red nodal tissue measuring in aggregate 1.7 x 1.5 x 0.4 cm. The specimen is submitted in its entirety for permanent processing.

The second container is additionally labeled "II-R lymph node". The specimen consists of an orange frozen section cassette labeled "B1" containing a fragment of tan-red nodal tissue measuring 1.7 x 1.1 x 0.3 cm. The specimen is submitted in its entirety for permanent processing.

The third container is additionally labeled "second IV-R lymph node". The specimen consists of tan-red nodal soft tissue measuring 2.2 x 1.7 x 0.3 cm that is in an orange frozen section cassette labeled "C1". It will be submitted in its entirety for permanent processing. Additionally found within the container are additional fragments of yellow fibroadipose tissue measuring 2.2 x 2.0 x 0.3 cm. These fragments will also be submitted in cassette C1.

[page 2 of 3]
The fourth container is additionally labeled "second II-R lymph node". The specimen consists of an orange frozen section cassette labeled "D1" containing red-tan nodal tissue measuring 2.1 x 1.8 x 0.4 cm. The specimen is submitted in its entirety for permanent processing.

The fifth container is additionally labeled "third IV-R lymph node". The specimen consists of an orange frozen section cassette labeled "E1" containing tan-red nodal tissue measuring 1.3 x 1.1 x 0.4 cm. The specimen is submitted in its entirety for permanent processing. Additionally identified in the container is a fragment of yellow fibroadipose tissue measuring 1.1 x 0.6 x 0.4 cm that will also be submitted in cassette E1.

The sixth container is additionally labeled "level X lymph node". The specimen consists of multiple fragments of tan-red fibroadipose and nodal tissue measuring in aggregate 1.2 x 0.6 x 0.4 cm. The specimen is submitted in its entirety per block summary.

The seventh container is additionally labeled "level VII lymph node". The specimen consists of an orange frozen section cassette labeled "G1". The cassette consists of multiple fragments of tan-red nodal tissue measuring in aggregate 3.0 x 2.4 x 0.5 cm. The specimen is submitted in its entirety per block summary.

The eighth container is additionally labeled "level VIII lymph node". The specimen consists of an orange frozen section cassette labeled "H1". The specimen consists of tan-red nodal tissue measuring 2.2 x 1.4 x 0.4 cm. The specimen is submitted in its entirety per block summary.

The ninth container is additionally labeled "level IX lymph node". The specimen consists of an orange frozen section cassette labeled "I1". The specimen consists of fragmented red-tan nodal tissue measuring in aggregate 1.3 x 1.2 x 0.4 cm. The specimen is submitted in its entirety per block summary. The tenth container is additionally labeled "level X-R lymph node". The specimen consists of multiple fragments of red-tan nodal tissue measuring 4.8 x 3.2 x 1.5 cm. Multiple possible lymph nodes are identified. The specimen (level X-R lymph node) is submitted in its entirety.

The eleventh container is additionally labeled "level XI lymph node". The specimen consists of red-tan nodal tissue measuring 1.1 x 1.2 x 0.6 cm. The lymph node is bisected and submitted in its entirety per block summary.

The twelfth container is additionally labeled "right upper lobe". The specimen consists of a lobe of lung as well as an orange frozen section cassette labeled "L1". The contents of the frozen section cassette will be resubmitted in its entirety per block summary. The lobe of lung measures 13.5 x 10.5 x 4.8 cm. It has been previously sectioned to reveal a tan-firm gritty subpleural lesion measuring 1.8 x 1.3 cm. There is no contraction of the overlying pleural surface. There is a curvilinear staple line measuring 10.5 cm. It appears to be well away (>3.0 cm) from the tan gritty mass. The pleural surface is red-purple and glistening and shows no obvious contracture or puckering. The tan gritty mass will be representatively submitted. Serial sectioning the lung reveals a red spongy parenchyma. A representative staple line margin will be submitted nearest the tan gritty mass. A peribronchial lymph node is identified. Sectioning reveals the mass to measure 4.5 x 5.2 x 4.1 cm. Representative sections of the mass will be submitted per block summary. In some areas the mass is focally hemorrhagic and necrotic and the parenchyma surrounding the mass has a somewhat greenish hue. In some areas there appear to be some adhesions overlying the pleura over the mass. The pleura over this area will be inked black.

The thirteenth container is additionally labeled "bronchial margin". The specimen consists of an orange frozen section cassette labeled "M1". The specimen consists of cartilaginous soft tissue measuring 0.6 x 0.5 x 0.3 cm. The specimen is submitted in its entirety for permanent section per block summary.

Block Summary

- A1- IV-R lymph node.
- B1- II-R lymph node.
- C1- Second IV-R lymph node.
- D1- Second II-R lymph node.
- E1- Third IV-R lymph node.
- F1- Level X lymph node.
- G1- Level VII lymph node.
- H1- Level VIII lymph node.
- I1- Level IX lymph node.
- J1- One level X-R lymph node, bisected.

[page 3 of 3]
- J2- Two level X-R lymph nodes, 1 bisected, 1 inked orange.
- J3- One level X-R lymph node, bisected.
- J4-J5- Level X-R lymph node, fragmented soft tissue.
- K1- Level XI lymph node.
- L1- Right upper lobe, frozen section.
- L2- Shaved staple line margin nearest the tumor.
- L3- Bisected peribronchial lymph node.
- L4-L8- Multiple representative sections of the gritty mass.
- L9-L10- Mass with respect to pleural surface.
- L11- Tumor adjacent to large airway.
- L12- Representative section of tumor.
- L13- Representative section of uninvolved lung.
- M1- Bronchial margin.

Microscopic Description

A microscopic examination has been performed.

SP Synoptic Report L: Thorax Lung

SPECIMEN: Lung

PROCEDURE: Lobectomy

SPECIMEN LATERALITY: Right

TUMOR SITE: Upper lobe

TUMOR SIZE: Greatest dimension: 5.2 cm

TUMOR FOCALITY: Unifocal

HISTOLOGIC TYPE: Squamous cell carcinoma

HISTOLOGIC GRADE: G2: Moderately differentiated

VISCERAL PLEURA INVASION: Present

PARENCHYMAL MARGIN: Uninvolved by invasive carcinoma

LYMPH-VASCULAR INVASION: Not identified

PRIMARY TUMOR (pT): pT2b: Tumor greater than 5 cm, but 7 cm or less in greatest dimension

REGIONAL LYMPH NODES (pN): pN0: No regional lymph node metastasis Number examined: 14, Number

involved: 0

Vx:
20% T 20% cr
<10% T 0% cr
Lung

HISPA Discrepancy		✓
Prior Malignancy History	OMF-OK	✓
Date Synchronous Primary Noted		✓

Source: NCI Genomic Data Commons file c2742ea4-8c85-4cb3-8822-45ebfbc8aabb (TCGA-98-A53D.3B02DAE4-711E-46B4-AFE4-ED65A7DD1AD5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).